Somatic mutation profile of tumor specimen C3L-09614-02 (aliquot CPT0492560006) from CPTAC case C3L-09614, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.1 years (20,109 days).
Specimen C3L-09614-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2208b865-2075-4a64-97c3-8401761876a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09614-31 (Blood Derived Normal), aliquot CPT0492610004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/703fe4d9-a1ea-46e5-a449-6f5b7c08fcf5

The open-access MAF lists 371 somatic variants for this specimen: 232 protein-altering or splice-affecting, 123 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 123, Nonsense Mutation 17, Intron 9, 3'Flank 3, Frame Shift Del 2, RNA 2, Splice Site 1, Splice Region 1, Translation Start Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DDX3X | c.1081C>T p.R361C (on ENST00000399959; = p.R362C on NM_001356.5) | Missense Mutation (SNP) | VAF 120/218 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs797045026, CM158053, COSV67863880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4366C>T p.Q1456* | Nonsense Mutation (SNP) | VAF 72/264 reads (27%) | catalogued as rs753033213; called by muse, mutect2, varscan2
- ABCA8 | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52206493; called by muse, mutect2, varscan2
- ABCC6 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 114/465 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228348; called by muse, mutect2, varscan2
- ABCC8 | c.4285G>A p.V1429I | Missense Mutation (SNP) | VAF 104/436 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as rs755577144; called by muse, mutect2, varscan2
- ABCG8 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 193/335 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.571); catalogued as rs1329698673, COSV55394142; called by muse, mutect2, varscan2
- ACSBG1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 97/340 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV99357673; called by muse, mutect2, varscan2
- ACSS3 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1247209581, COSV54084933; called by muse, mutect2, varscan2
- ADAM29 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 117/383 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV63667294; called by muse, mutect2, varscan2
- ADAM7 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs267601867, COSV51545738; called by muse, mutect2, varscan2
- ADGRL3 | c.4699G>A p.E1567K (on ENST00000506720 / NM_001322402.2; = p.E1456K on NM_015236.6) | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1020254329; called by muse, mutect2, varscan2
- ADGRV1 | c.11869G>A p.A3957T | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV67988961; called by muse, mutect2, varscan2
- ADH1C | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs770280294; called by muse, mutect2, varscan2
- AHNAK2 | c.6115C>T p.Q2039* | Nonsense Mutation (SNP) | VAF 135/318 reads (42%) | catalogued as COSV60919654; called by muse, mutect2, varscan2
- AK9 | c.5318C>T p.S1773L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1386474497, COSV69849868; called by muse, mutect2, varscan2
- ALPK3 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 87/337 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs1370515564; called by muse, mutect2, varscan2
- ALS2 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 161/256 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV51892479; called by muse, mutect2, varscan2
- ANK2 | c.9145C>T p.R3049W | Missense Mutation (SNP) | VAF 95/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201870166, COSV52158351; called by muse, mutect2, varscan2
- ANO2 | c.2657C>T p.P886L (on ENST00000356134 / NM_001278597.3; = p.P890L on NM_001278596.3) | Missense Mutation (SNP) | VAF 98/362 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs754149600, COSV59039805; called by muse, mutect2, varscan2
- ANO4 | c.628C>T p.R210W (on ENST00000392977 / NM_001286615.2; = p.R175W on NM_178826.4) | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as rs372521580; called by muse, mutect2, varscan2
- AP000812.4 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs760228040; called by muse, mutect2, varscan2
- BTBD18 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 105/350 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs958047276; called by muse, mutect2, varscan2
- CA5A | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59239032; called by muse, mutect2, varscan2
- CATSPERB | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 96/409 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV56422977; called by muse, mutect2
- CFAP46 | c.6775G>A p.E2259K | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1425773575; called by muse, mutect2, varscan2
- CFAP54 | c.4452G>A p.M1484I | Missense Mutation (SNP) | VAF 150/417 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1293532960; called by muse, mutect2, varscan2
- CNGA1 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 121/407 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs373782782; called by muse, mutect2, varscan2
- CSMD2 | c.4507G>A p.D1503N | Missense Mutation (SNP) | VAF 215/341 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs199793319, COSV53874530; called by muse, mutect2, varscan2
- CTXND2 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 120/448 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs1474649106; called by muse, mutect2, varscan2
- CYP21A2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 116/608 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1410365935, COSV64490672; called by muse, mutect2, varscan2
- CYP4F2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 359/587 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs750598459, COSV50000283; called by muse, mutect2, varscan2
- DGKI | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55950828; called by muse, mutect2, varscan2
- DNAH5 | c.9530C>T p.S3177L | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54246092; called by muse, mutect2, varscan2
- DPYS | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 107/455 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV60912098; called by muse, mutect2, varscan2
- ELOA3D | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 324/5194 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1233235919; called by muse, mutect2
- ENPP7 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs782599171, COSV100093647; called by muse, mutect2, varscan2
- EXOC3L4 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs757105801, COSV66295448, COSV66295527; called by muse, varscan2
- FADS6 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 151/579 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59602546; called by muse, mutect2, varscan2
- FASTKD5 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs768753034; called by muse, mutect2, varscan2
- GHR | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 122/453 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50113625; called by muse, mutect2, varscan2
- GJA8 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 232/393 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV53788818; called by muse, mutect2, varscan2
- GRM8 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 278/619 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV58820387, COSV58853973; called by muse, mutect2, varscan2
- GSTCD | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 103/422 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs908538263; called by muse, mutect2, varscan2
- HAL | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs367677601; called by muse, mutect2, varscan2
- HS3ST4 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs749218404, COSV58830788; called by muse, mutect2, varscan2
- HTR3B | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366929014, COSV99492373; called by muse, mutect2, varscan2
- IGFBP4 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 142/441 reads (32%) | catalogued as rs942618272, COSV54096838; called by muse, mutect2, varscan2
- IGHV3-33 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 131/218 reads (60%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.038); catalogued as rs753354905; called by muse, mutect2, varscan2
- IGLV1-44 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as rs1479562632; called by muse, mutect2
- IGLV4-60 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1382718095; called by muse, mutect2
- INF2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 138/418 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1236232532; called by muse, mutect2, varscan2
- KCNH2 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 218/529 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs794728371, COSV51225823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT2 | c.3388C>T p.R1130W | Missense Mutation (SNP) | VAF 190/320 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs188819863; called by muse, mutect2, varscan2
- KIR2DL1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs113536578, COSV52415400; called by muse, varscan2
- KIRREL2 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 270/492 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as rs777136300; called by muse, mutect2, varscan2
- KRT37 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 110/393 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs775896953; called by muse, mutect2, varscan2
- KRT6A | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 153/524 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381026519, COSV58108217; called by muse, mutect2, varscan2
- LGALS4 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 204/394 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV57044675; called by muse, mutect2, varscan2
- LILRA2 | c.1359G>A p.M453I (on ENST00000391738 / NM_001130917.3; = p.M436I on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 288/660 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV99252728; called by muse, varscan2
- LIMS1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 192/352 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs1324676493, COSV100185715; called by muse, mutect2, varscan2
- LRRC36 | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV52078628; called by muse, mutect2, varscan2
- MGAT5B | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1255254383, COSV100047240; called by muse, mutect2, varscan2
- MMRN1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV53335491; called by muse, mutect2, varscan2
- MROH2B | c.3883C>T p.L1295F | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV101270440; called by muse, mutect2, varscan2
- MUC16 | c.16898C>T p.S5633F | Missense Mutation (SNP) | VAF 180/332 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1446280776, COSV67445101; called by muse, varscan2
- MUC5AC | c.309C>A p.C103* | Nonsense Mutation (SNP) | VAF 128/484 reads (26%) | catalogued as COSV100650536; called by muse, mutect2, varscan2
- MYH8 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101238579; called by muse, mutect2, varscan2
- MYRFL | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs184470223; called by muse, mutect2, varscan2
- NLRP8 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV52590272; called by muse, mutect2, varscan2
- NOS1 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 66/311 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs763630164, COSV57623006; called by muse, mutect2, varscan2
- NRXN1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 177/288 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100453094; called by muse, mutect2, varscan2
- NUMA1 | c.5368C>G p.L1790V | Missense Mutation (SNP) | VAF 99/411 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.173); catalogued as rs367864451; called by muse, mutect2, varscan2
- OR10A7 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 119/449 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1468419370, COSV58279213; called by muse, mutect2, varscan2
- OR2F2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 317/642 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283803; called by muse, mutect2, varscan2
- OR2G6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 206/330 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs768636962, COSV58576113; called by muse, mutect2, varscan2
- OR4A16 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); catalogued as COSV59041753, COSV59043563; called by muse, mutect2, varscan2
- OR4A47 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 97/410 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.266); catalogued as rs1414734520; called by muse, mutect2, varscan2
- OR51G1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429166, COSV58968600; called by muse, varscan2
- PCDH15 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs370442031, COSV57263745; called by muse, mutect2, varscan2
- PCDHB5 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 168/687 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1489928107, COSV50654456; called by muse, mutect2
- PGAM4 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 38/459 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1569549340; called by muse, mutect2
- PIK3C3 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 152/333 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56284071; called by muse, mutect2, varscan2
- PLCB4 | c.1793C>A p.S598* | Nonsense Mutation (SNP) | VAF 35/253 reads (14%) | catalogued as COSV53794946; called by muse, mutect2, varscan2
- PRAMEF6 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs753930069, COSV100755867; called by muse, mutect2, varscan2
- PRSS51 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 186/446 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs564336741; called by muse, mutect2, varscan2
- PSD2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1415852750, COSV51210114, COSV99216993; called by muse, mutect2, varscan2
- PSMA8 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs761107220, COSV57604509; called by muse, mutect2, varscan2
- PTPN22 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 159/259 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs201429780, COSV63085985; called by muse, mutect2, varscan2
- PTPRR | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51737934; called by muse, mutect2, varscan2
- PYCR3 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 296/716 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs756007883; called by muse, mutect2, varscan2
- RBMXL3 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 174/324 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as rs782641942, COSV57746790; called by muse, mutect2, varscan2
- REN | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 103/387 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs191049685, COSV65817317; called by muse, mutect2, varscan2
- SALL1 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51753548; called by muse, mutect2, varscan2
- SARDH | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 92/380 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs755017202, COSV53836478; called by muse, mutect2, varscan2
- SCN5A | c.5189C>T p.P1730L (on ENST00000333535 / NM_198056.3; = p.P1729L on NM_000335.5) | Missense Mutation (SNP) | VAF 114/492 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs752599203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHISA9 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 157/525 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV69631950, COSV69633525; called by muse, mutect2, varscan2
- SLC6A3 | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 141/472 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV99548708; called by muse, mutect2, varscan2
- SLC8A3 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 111/399 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63523816; called by muse, mutect2, varscan2
- SMCO2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs1486168412; called by muse, mutect2, varscan2
- SMG7 | c.2464C>T p.L822F | Missense Mutation (SNP) | VAF 277/474 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as rs751372328; called by muse, mutect2, varscan2
- SPEN | c.4423C>T p.R1475* | Nonsense Mutation (SNP) | VAF 271/474 reads (57%) | catalogued as COSV65360605; called by muse, mutect2, varscan2
- SRARP | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 141/260 reads (54%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs369643391; called by muse, mutect2, varscan2
- STAC | c.975G>A p.G325= | Splice Region (SNP) | VAF 51/191 reads (27%) | catalogued as COSV56211068; called by muse, mutect2, varscan2
- STEAP2 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 199/430 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99840512; called by muse, mutect2, varscan2
- SV2A | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs1222575049; called by muse, mutect2, varscan2
- SYTL4 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as COSV99343067; called by muse, mutect2, varscan2
- TAAR2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV51579738; called by muse, mutect2, varscan2
- TACC3 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 119/407 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs1560299956; called by muse, mutect2, varscan2
- TCF4 | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 94/467 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61890724; called by muse, mutect2, varscan2
- TENM2 | c.4522G>A p.G1508R (on ENST00000518659 / NM_001122679.2; = p.G1269R on NM_001080428.3) | Missense Mutation (SNP) | VAF 114/451 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs548869968; called by muse, mutect2, varscan2
- TG | c.4310G>A p.W1437* | Nonsense Mutation (SNP) | VAF 228/498 reads (46%) | catalogued as CM063191, COSV55074703; called by muse, mutect2, varscan2
- TMEM235 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as rs555201618; called by muse, mutect2, varscan2
- TRAV20 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1453037638; called by muse, mutect2, varscan2
- TRPM7 | c.4388C>T p.S1463F | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs185367011, COSV100539268; called by muse, mutect2, varscan2
- TSEN54 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 107/361 reads (30%) | catalogued as rs201775186, COSV99390135; called by muse, mutect2, varscan2
- TST | c.61A>G p.R21G | Missense Mutation (SNP) | VAF 141/418 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1196642212; called by muse, mutect2, varscan2
- USP2 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 141/508 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV99490037; called by muse, mutect2, varscan2
- USP28 | c.2912C>T p.S971F | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV50156509; called by muse, mutect2, varscan2
- VWA5A | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as rs765337016, COSV64412674; called by muse, varscan2
- XKR9 | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV68773013, COSV68773663; called by muse, mutect2, varscan2
- XPO5 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366410108, COSV54828519; called by muse, mutect2, varscan2
- ZAN | c.6701G>T p.R2234L | Missense Mutation (SNP) | VAF 64/560 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs560129889, COSV61808185, COSV61809111; called by mutect2, varscan2
- ZNF628 | c.2639G>T p.G880V | Missense Mutation (SNP) | VAF 191/816 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52702194; called by muse, mutect2, varscan2
- ZNF862 | c.2674G>T p.E892* | Nonsense Mutation (SNP) | VAF 66/726 reads (9%) | catalogued as COSV99783813; called by muse, mutect2
- ABCC12 | c.3452G>A p.G1151E | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACAN | c.4178G>A p.G1393E | Missense Mutation (SNP) | VAF 76/645 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, varscan2
- ADGRV1 | c.2913G>A p.M971I | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AL592490.1 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ANK1 | c.3485G>A p.S1162N | Missense Mutation (SNP) | VAF 117/584 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD12 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 82/279 reads (29%) | called by muse, mutect2, varscan2
- ANKRD36C | c.5199G>T p.E1733D | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- AP000812.4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 73/284 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APOB | c.8554G>A p.G2852R | Missense Mutation (SNP) | VAF 212/397 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.6254C>T p.S2085F | Missense Mutation (SNP) | VAF 123/389 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCAR1 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 156/479 reads (33%) | called by muse, mutect2, varscan2
- BIRC6 | c.10347-1G>A p.X3449_splice | Splice Site (SNP) | VAF 76/141 reads (54%) | called by muse, mutect2, varscan2
- BPIFB4 | c.937A>G p.N313D | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- BRAT1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 134/616 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- BTBD18 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 103/348 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTD | c.1281del p.H427Qfs*54 | Frame Shift Del (DEL) | VAF 136/468 reads (29%) | called by mutect2, pindel*, varscan2
- C1S | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C7 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CATSPER1 | c.1319_1342delinsA p.I440Nfs*3 | Frame Shift Del (DEL) | VAF 91/496 reads (18%) | called by pindel, varscan2*
- CEL | c.2114C>T p.P705L (on ENST00000673714; = p.P702L on NM_001807.6) | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, varscan2
- CES1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 126/817 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CNGB3 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 156/399 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL11A2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 210/892 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- COL2A1 | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 125/373 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL8A2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 243/442 reads (55%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIPK1C | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 351/745 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DNAH7 | c.10736T>C p.L3579P | Missense Mutation (SNP) | VAF 159/287 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM187B | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 236/424 reads (56%) | called by muse, mutect2, varscan2
- FAT3 | c.9524G>A p.G3175D | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.12328G>A p.G4110R | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FBLN5 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 74/225 reads (33%) | called by muse, mutect2, varscan2
- FOXP2 | c.1630A>G p.N544D | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FRMD3 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 94/313 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GAL3ST1 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 143/521 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GAL3ST3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- GAS2L3 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 133/402 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- GBP7 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 196/342 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GGT5 | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 104/439 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- GLI1 | c.3059G>A p.G1020E | Missense Mutation (SNP) | VAF 133/471 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- HDAC9 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 258/547 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPG2 | c.6314C>T p.P2105L | Missense Mutation (SNP) | VAF 181/345 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HTR3A | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 128/482 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- IGLV1-47 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- IRX2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 116/344 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITLN2 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 214/342 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDR | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- KIAA1522 | c.1687C>T p.P563S (on ENST00000373480 / NM_001198972.2; = p.P622S on NM_020888.3) | Missense Mutation (SNP) | VAF 259/471 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- KLHL13 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 93/157 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LILRB1 | c.244A>C p.T82P (on ENST00000427581; = p.T46P on NM_006669.6) | Missense Mutation (SNP) | VAF 88/611 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LMO3 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LMTK3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 155/285 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- MAP1LC3A | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 103/372 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MAP2K1 | c.739T>C p.W247R | Missense Mutation (SNP) | VAF 117/402 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDGA1 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 235/570 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- METTL9 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRC2 | c.3194G>A p.G1065D | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MUC16 | c.25928C>T p.S8643L | Missense Mutation (SNP) | VAF 243/419 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- MUC16 | c.22286G>A p.G7429D | Missense Mutation (SNP) | VAF 298/471 reads (63%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MUC5AC | c.310A>C p.N104H | Missense Mutation (SNP) | VAF 126/483 reads (26%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYH7B | c.5366T>A p.V1789E | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- MYO6 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDUFS4 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NGEF | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 190/342 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRX1 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 86/393 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.129); called by muse, mutect2
- NOS1 | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NWD1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 225/402 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PATL1 | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PDZRN3 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 151/497 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEC | c.8885C>T p.P2962L (on ENST00000322810 / NM_201380.4; = p.P2852L on NM_000445.5) | Missense Mutation (SNP) | VAF 430/1013 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PLXNA4 | c.4018G>A p.V1340I | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- POLR2B | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 101/349 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- POU6F2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 267/661 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PPARGC1B | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 128/458 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPP1R3G | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 141/531 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PTDSS2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 115/411 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PYCR3 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 299/714 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- RAF1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- RASIP1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 282/515 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- RBFOX1 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RBMY1F | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- RPA4 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 109/211 reads (52%) | called by mutect2, varscan2
- SCN4A | c.3367G>A p.G1123R | Missense Mutation (SNP) | VAF 98/400 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SEMG1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 108/403 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SHISA8 | c.38C>T p.P13L (on ENST00000457093; = p.P46L on NM_001207020.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- SLC52A1 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 100/365 reads (27%) | called by muse, mutect2, varscan2
- SMARCC1 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- SNED1 | c.4098G>A p.W1366* | Nonsense Mutation (SNP) | VAF 213/383 reads (56%) | called by muse, mutect2, varscan2
- SNX18 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 111/406 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SORCS3 | c.1153T>A p.F385I | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPARCL1 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPEG | c.5117G>A p.G1706E | Missense Mutation (SNP) | VAF 168/285 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN5 | c.6076G>A p.A2026T | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- STON1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 222/372 reads (60%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- SYCP2 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- SYT16 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TMEM94 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRANK1 | c.3589C>T p.P1197S | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPC7 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UNC13C | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 129/449 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- WDR38 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 92/292 reads (32%) | called by muse, mutect2, varscan2
- WRN | c.3935T>C p.V1312A | Missense Mutation (SNP) | VAF 214/463 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZDHHC15 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZDHHC19 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ZNF395 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 208/493 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF510 | c.808G>C p.V270L | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF722P | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 256/626 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.348G>A p.R116= | Silent (SNP) | VAF 78/405 reads (19%) | catalogued as COSV58447351; called by muse, mutect2, varscan2
- AMIGO2 | c.1506G>A p.G502= | Silent (SNP) | VAF 94/350 reads (27%) | catalogued as COSV56976085; called by muse, mutect2, varscan2
- ANAPC2 | c.855C>T p.F285= | Silent (SNP) | VAF 115/371 reads (31%) | catalogued as rs750771616; called by muse, mutect2, varscan2
- ANO1 | c.2736C>T p.I912= | Silent (SNP) | VAF 88/333 reads (26%) | catalogued as rs747605502; called by muse, mutect2, varscan2
- ANXA2 | c.942C>T p.S314= | Silent (SNP) | VAF 51/224 reads (23%) | called by muse, mutect2, varscan2
- BCO1 | c.1494G>A p.T498= | Silent (SNP) | VAF 129/413 reads (31%) | catalogued as rs544006390; called by muse, mutect2, varscan2
- CABS1 | c.432C>T p.I144= | Silent (SNP) | VAF 71/262 reads (27%) | catalogued as COSV56732901; called by muse, mutect2, varscan2
- CACNA1I | c.1182C>T p.L394= | Silent (SNP) | VAF 82/309 reads (27%) | catalogued as rs1200610839; called by muse, mutect2, varscan2
- CANX | c.1489C>T p.L497= | Silent (SNP) | VAF 90/307 reads (29%) | catalogued as rs762161407; called by muse, mutect2, varscan2
- CCDC63 | c.660C>T p.A220= | Silent (SNP) | VAF 69/251 reads (27%) | called by muse, mutect2, varscan2
- CD46 | c.969T>C p.P323= | Silent (SNP) | VAF 148/279 reads (53%) | called by muse, mutect2, varscan2
- CDCA2 | c.804C>T p.L268= | Silent (SNP) | VAF 51/315 reads (16%) | called by muse, mutect2, varscan2
- CDH20 | c.1986C>T p.I662= | Silent (SNP) | VAF 143/576 reads (25%) | catalogued as rs781612330, COSV53005997; called by muse, mutect2, varscan2
- CDH9 | c.1323C>T p.F441= | Silent (SNP) | VAF 98/387 reads (25%) | catalogued as COSV50419931; called by muse, mutect2, varscan2
- CES5A | c.1122C>T p.I374= | Silent (SNP) | VAF 102/360 reads (28%) | called by muse, mutect2, varscan2
- CFAP46 | c.6057G>A p.E2019= | Silent (SNP) | VAF 124/308 reads (40%) | catalogued as rs755681328; called by muse, mutect2, varscan2
- CKAP4 | c.1311C>T p.L437= | Silent (SNP) | VAF 125/471 reads (27%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.3897G>A p.K1299= | Silent (SNP) | VAF 193/870 reads (22%) | called by muse, varscan2
- COBL | c.204C>T p.V68= | Silent (SNP) | VAF 104/538 reads (19%) | called by muse, mutect2
- COL5A1 | c.4806G>T p.V1602= | Silent (SNP) | VAF 67/470 reads (14%) | catalogued as COSV100880209; called by muse, mutect2, varscan2
- CSMD1 | c.2637C>T p.I879= (on ENST00000520002; = p.I878= on NM_033225.6) | Silent (SNP) | VAF 110/521 reads (21%) | called by muse, mutect2, varscan2
- CSMD2 | c.3399G>A p.G1133= | Silent (SNP) | VAF 261/454 reads (57%) | catalogued as COSV53944548; called by muse, mutect2, varscan2
- CYP4F11 | c.1563G>A p.A521= | Silent (SNP) | VAF 112/205 reads (55%) | catalogued as rs1296561213, COSV56125770; called by muse, mutect2, varscan2
- CYP4X1 | c.135C>T p.P45= | Silent (SNP) | VAF 273/452 reads (60%) | called by muse, mutect2, varscan2
- DDIT4L | c.492C>T p.F164= | Silent (SNP) | VAF 102/327 reads (31%) | called by muse, mutect2, varscan2
- DHRS4 | c.439C>T p.L147= | Silent (SNP) | VAF 107/398 reads (27%) | called by muse, mutect2, varscan2
- DHX16 | c.1515C>T p.F505= | Silent (SNP) | VAF 97/563 reads (17%) | called by muse, mutect2, varscan2
- DIPK1C | c.633C>T p.P211= | Silent (SNP) | VAF 350/750 reads (47%) | catalogued as rs1002792589; called by muse, mutect2, varscan2
- DNAI2 | c.1374C>T p.L458= | Silent (SNP) | VAF 129/422 reads (31%) | called by muse, mutect2, varscan2
- DPF3 | c.924C>T p.T308= | Silent (SNP) | VAF 110/382 reads (29%) | called by muse, mutect2, varscan2
- DPPA2 | c.150C>A p.V50= | Silent (SNP) | VAF 107/252 reads (42%) | catalogued as COSV101524762; called by muse, mutect2, varscan2
- EED | c.718C>T p.L240= | Silent (SNP) | VAF 95/354 reads (27%) | catalogued as rs1476994169; called by muse, mutect2, varscan2
- EPHA6 | c.2244G>A p.G748= (on ENST00000389672 / NM_001080448.3; = p.G140= on NM_173655.4) | Silent (SNP) | VAF 92/314 reads (29%) | catalogued as COSV67562555; called by muse, mutect2, varscan2
- FCRL5 | c.1395C>T p.S465= | Silent (SNP) | VAF 125/216 reads (58%) | catalogued as rs926826526, COSV62521968; called by muse, mutect2, varscan2
- FLRT2 | c.132G>A p.R44= | Silent (SNP) | VAF 139/477 reads (29%) | catalogued as rs1166701000, COSV58145802; called by muse, mutect2, varscan2
- FOXP2 | c.1629T>A p.R543= | Silent (SNP) | VAF 57/329 reads (17%) | called by muse, mutect2, varscan2
- GALNT6 | c.750C>T p.I250= | Silent (SNP) | VAF 131/488 reads (27%) | catalogued as COSV100695573, COSV62543621; called by muse, mutect2, varscan2
- GPD1 | c.529C>T p.L177= | Silent (SNP) | VAF 99/321 reads (31%) | called by muse, mutect2, varscan2
- GPR174 | c.240G>A p.L80= | Silent (SNP) | VAF 154/286 reads (54%) | called by muse, mutect2, varscan2
- GPR55 | c.945G>A p.T315= | Silent (SNP) | VAF 136/258 reads (53%) | catalogued as rs750679484, COSV67407349; called by muse, mutect2, varscan2
- GRAP | c.621C>T p.F207= | Silent (SNP) | VAF 170/571 reads (30%) | called by muse, mutect2, varscan2
- IFRD2 | c.753T>C p.L251= | Silent (SNP) | VAF 106/371 reads (29%) | called by muse, mutect2, varscan2
- IGHA1 | c.159C>T p.F53= | Silent (SNP) | VAF 172/535 reads (32%) | called by muse, varscan2
- KCNB2 | c.1425C>T p.S475= | Silent (SNP) | VAF 207/506 reads (41%) | catalogued as COSV73049433; called by muse, mutect2, varscan2
- KCNH5 | c.885C>T p.I295= | Silent (SNP) | VAF 87/314 reads (28%) | catalogued as rs1230839550, COSV59752184; called by muse, mutect2, varscan2
- KCNJ14 | c.1047C>T p.F349= | Silent (SNP) | VAF 265/443 reads (60%) | called by muse, mutect2, varscan2
- KIAA1522 | c.1686C>T p.S562= (on ENST00000373480 / NM_001198972.2; = p.S621= on NM_020888.3) | Silent (SNP) | VAF 256/467 reads (55%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4272C>T p.I1424= | Silent (SNP) | VAF 138/482 reads (29%) | called by muse, mutect2, varscan2
- KLF7 | c.432C>T p.L144= | Silent (SNP) | VAF 297/530 reads (56%) | catalogued as rs776657301; called by muse, mutect2, varscan2
- KRT84 | c.1689C>T p.V563= | Silent (SNP) | VAF 125/420 reads (30%) | catalogued as rs368450430; called by muse, mutect2, varscan2
- KRTAP4-16 | c.546C>T p.A182= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- LINGO2 | c.183C>T p.I61= | Silent (SNP) | VAF 114/248 reads (46%) | catalogued as COSV58059148, COSV58064362; called by muse, mutect2, varscan2
- MAP1LC3A | c.288G>A p.A96= | Silent (SNP) | VAF 105/372 reads (28%) | catalogued as rs550144245; called by muse, mutect2, varscan2
- MAP3K5 | c.3126C>T p.F1042= | Silent (SNP) | VAF 89/300 reads (30%) | catalogued as rs752071478; called by muse, mutect2, varscan2
- MEI1 | c.1188C>T p.I396= | Silent (SNP) | VAF 84/257 reads (33%) | called by muse, mutect2, varscan2
- MIP | c.72C>T p.V24= | Silent (SNP) | VAF 108/431 reads (25%) | called by muse, mutect2, varscan2
- MVK | c.1188C>T p.L396= | Silent (SNP) | VAF 83/226 reads (37%) | called by muse, mutect2, varscan2
- MYO5B | c.951G>A p.V317= | Silent (SNP) | VAF 97/271 reads (36%) | called by muse, mutect2, varscan2
- NAP1L2 | c.771G>A p.L257= | Silent (SNP) | VAF 129/232 reads (56%) | catalogued as rs764923356, COSV65172904; called by muse, mutect2, varscan2
- NLRC5 | c.3066C>T p.A1022= | Silent (SNP) | VAF 74/287 reads (26%) | called by muse, mutect2, varscan2
- NNMT | c.330G>A p.V110= | Silent (SNP) | VAF 80/316 reads (25%) | called by muse, mutect2, varscan2
- NOTCH1 | c.6606C>T p.S2202= | Silent (SNP) | VAF 178/515 reads (35%) | called by muse, mutect2, varscan2
- NPIPB2 | c.435G>A p.T145= (on ENST00000399147; = p.T5= on NM_001355514.1) | Silent (SNP) | VAF 105/360 reads (29%) | catalogued as rs765487478, COSV63638822; called by muse, mutect2, varscan2
- NPR3 | c.1017G>A p.V339= | Silent (SNP) | VAF 89/381 reads (23%) | called by muse, mutect2, varscan2
- NUP93 | c.1953C>T p.P651= | Silent (SNP) | VAF 68/296 reads (23%) | catalogued as rs1197265501; called by muse, varscan2
- NYNRIN | c.3162C>T p.I1054= | Silent (SNP) | VAF 134/460 reads (29%) | catalogued as rs1052949659, COSV66841326; called by muse, mutect2, varscan2
- OR10G7 | c.561C>T p.A187= | Silent (SNP) | VAF 132/512 reads (26%) | catalogued as COSV57868348; called by muse, mutect2, varscan2
- OR13C3 | c.642C>T p.V214= | Silent (SNP) | VAF 108/414 reads (26%) | called by muse, mutect2
- OR51G2 | c.342C>T p.F114= | Silent (SNP) | VAF 118/420 reads (28%) | catalogued as rs1564806340, COSV100432220; called by muse, mutect2, varscan2
- OR51T1 | c.654C>T p.F218= | Silent (SNP) | VAF 116/394 reads (29%) | catalogued as rs1472996618, COSV100434440; called by muse, mutect2, varscan2
- OR52B4 | c.777C>T p.F259= | Silent (SNP) | VAF 112/412 reads (27%) | called by muse, mutect2, varscan2
- OR5G3 | c.708G>A p.K236= | Silent (SNP) | VAF 92/334 reads (28%) | called by muse, mutect2, varscan2
- OSBP2 | c.672C>T p.C224= | Silent (SNP) | VAF 83/322 reads (26%) | called by muse, mutect2, varscan2
- OSMR | c.2712C>T p.S904= | Silent (SNP) | VAF 90/306 reads (29%) | catalogued as rs776666994; called by muse, mutect2, varscan2
- OXGR1 | c.312C>T p.F104= | Silent (SNP) | VAF 84/330 reads (25%) | catalogued as rs868112579; called by muse, mutect2, varscan2
- OXTR | c.1080G>A p.T360= | Silent (SNP) | VAF 85/364 reads (23%) | catalogued as rs757230261, COSV57478911; called by muse, mutect2, varscan2
- PAPPA | c.1975C>T p.L659= | Silent (SNP) | VAF 126/456 reads (28%) | catalogued as COSV60282783; called by muse, mutect2, varscan2
- PCDH12 | c.1383G>A p.E461= | Silent (SNP) | VAF 110/452 reads (24%) | called by muse, mutect2, varscan2
- PCDH17 | c.3327G>A p.R1109= | Silent (SNP) | VAF 144/516 reads (28%) | catalogued as COSV64977590; called by muse, mutect2, varscan2
- PCDHA9 | c.225G>A p.L75= | Silent (SNP) | VAF 163/566 reads (29%) | called by muse, mutect2, varscan2
- PDE6A | c.2130C>T p.I710= | Silent (SNP) | VAF 62/250 reads (25%) | catalogued as rs750000569, COSV54927344; called by muse, mutect2, varscan2
- PEG3 | c.1116G>A p.R372= | Silent (SNP) | VAF 201/435 reads (46%) | catalogued as COSV55626213, COSV55645682; called by muse, mutect2, varscan2
- PIGT | c.1008C>T p.L336= | Silent (SNP) | VAF 112/318 reads (35%) | called by muse, mutect2, varscan2
- PLXDC1 | c.1380C>T p.I460= | Silent (SNP) | VAF 64/270 reads (24%) | catalogued as rs376208206; called by muse, mutect2, varscan2
- PNPLA6 | c.1911C>T p.F637= (on ENST00000414982 / NM_001166111.2; = p.F589= on NM_006702.5) | Silent (SNP) | VAF 267/471 reads (57%) | called by muse, mutect2, varscan2
- PPP1R9B | c.795C>T p.A265= | Silent (SNP) | VAF 166/589 reads (28%) | called by muse, varscan2
- PSEN2 | c.300C>T p.I100= | Silent (SNP) | VAF 104/268 reads (39%) | catalogued as rs200801915, COSV60914819; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RAPGEF1 | c.189C>G p.L63= | Silent (SNP) | VAF 102/362 reads (28%) | called by muse, mutect2, varscan2
- RASAL1 | c.1791G>A p.G597= | Silent (SNP) | VAF 112/418 reads (27%) | catalogued as rs1349126439, COSV55660301; called by muse, mutect2, varscan2
- RHOU | c.372C>T p.F124= | Silent (SNP) | VAF 138/331 reads (42%) | catalogued as rs765539039, COSV64209128; called by muse, mutect2, varscan2
- RP1 | c.1302C>T p.I434= | Silent (SNP) | VAF 95/459 reads (21%) | catalogued as COSV55117282; called by muse, mutect2, varscan2
- RP1 | c.2208C>T p.S736= | Silent (SNP) | VAF 95/448 reads (21%) | called by muse, mutect2, varscan2
- RPA4 | c.123C>T p.V41= | Silent (SNP) | VAF 114/225 reads (51%) | called by muse, mutect2, varscan2
- RTL1 | c.1272G>A p.A424= | Silent (SNP) | VAF 137/469 reads (29%) | catalogued as rs763881276, COSV66016586; called by muse, mutect2, varscan2
- RTRAF | c.87C>T p.I29= | Silent (SNP) | VAF 70/251 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.10077C>T p.F3359= | Silent (SNP) | VAF 128/283 reads (45%) | called by muse, mutect2, varscan2
- SCRN2 | c.1215C>T p.P405= | Silent (SNP) | VAF 134/492 reads (27%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.2409C>T p.P803= (on ENST00000369774 / NM_001365079.1; = p.P775= on NM_014631.2) | Silent (SNP) | VAF 133/304 reads (44%) | called by muse, mutect2, varscan2
- SLC25A22 | c.687C>T p.F229= | Silent (SNP) | VAF 135/454 reads (30%) | called by muse, mutect2, varscan2
- SLC27A1 | c.6G>A p.R2= | Silent (SNP) | VAF 198/352 reads (56%) | catalogued as rs1375215661; called by muse, mutect2, varscan2
- SMARCC1 | c.2031C>T p.S677= | Silent (SNP) | VAF 121/451 reads (27%) | called by muse, mutect2, varscan2
- SMIM10L2A | c.174C>T p.F58= | Silent (SNP) | VAF 94/185 reads (51%) | called by muse, varscan2
- SNX18 | c.993C>T p.S331= | Silent (SNP) | VAF 108/402 reads (27%) | catalogued as COSV100410248; called by muse, mutect2, varscan2
- SPPL2B | c.867C>T p.F289= | Silent (SNP) | VAF 214/362 reads (59%) | catalogued as rs1421757196; called by muse, mutect2, varscan2
- TAL2 | c.84C>T p.L28= | Silent (SNP) | VAF 119/393 reads (30%) | catalogued as rs765518830, COSV100482437; called by muse, mutect2, varscan2
- TDRD12 | c.1717C>T p.L573= | Silent (SNP) | VAF 46/255 reads (18%) | called by muse, mutect2, varscan2
- TEK | c.1299G>A p.V433= | Silent (SNP) | VAF 100/247 reads (40%) | called by muse, mutect2, varscan2
- TENM3 | c.93G>A p.E31= | Silent (SNP) | VAF 119/393 reads (30%) | catalogued as rs780435771; called by muse, mutect2, varscan2
- TMEM225B | c.234C>T p.F78= | Silent (SNP) | VAF 90/454 reads (20%) | called by muse, mutect2, varscan2
- TMPRSS2 | c.873C>T p.I291= | Silent (SNP) | VAF 155/497 reads (31%) | catalogued as rs113436669, COSV59823505; called by muse, mutect2, varscan2
- TNXB | c.11466G>A p.S3822= (on ENST00000647633; = p.S3575= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 152/1636 reads (9%) | catalogued as rs764496579, COSV64482927; called by muse, mutect2
- TRANK1 | c.273C>T p.F91= | Silent (SNP) | VAF 92/329 reads (28%) | called by muse, mutect2, varscan2
- TRIM77 | c.1230C>T p.F410= | Silent (SNP) | VAF 104/438 reads (24%) | called by muse, mutect2, varscan2
- TTLL5 | c.2242C>T p.L748= | Silent (SNP) | VAF 75/304 reads (25%) | called by muse, mutect2, varscan2
- UBR2 | c.4335C>T p.F1445= | Silent (SNP) | VAF 184/410 reads (45%) | catalogued as COSV100867527; called by muse, mutect2, varscan2
- UGT2B15 | c.936G>A p.S312= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as rs1473789900; called by muse, mutect2, varscan2
- USP2 | c.660C>T p.V220= | Silent (SNP) | VAF 139/502 reads (28%) | called by muse, mutect2, varscan2
- WDR62 | c.3765C>T p.S1255= | Silent (SNP) | VAF 317/531 reads (60%) | called by muse, mutect2, varscan2
- WFDC2 | c.276C>T p.L92= | Silent (SNP) | VAF 141/512 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7152C>T p.G2384= | Silent (SNP) | VAF 246/531 reads (46%) | catalogued as COSV51450886; called by muse, mutect2, varscan2
- ZNF383 | c.1203G>A p.K401= | Silent (SNP) | VAF 17/501 reads (3%) | called by muse, mutect2
- ZNF407 | c.3021C>T p.S1007= | Silent (SNP) | VAF 188/441 reads (43%) | catalogued as rs372408214, COSV55249684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF532 | c.3579C>T p.I1193= | Silent (SNP) | VAF 284/586 reads (48%) | called by muse, mutect2, varscan2
- AANAT | chr17:76466178 G>A | 5'Flank (SNP) | VAF 78/334 reads (23%) | called by muse, mutect2, varscan2
- CXCL12 | c.267-2605G>A | Intron (SNP) | VAF 53/159 reads (33%) | catalogued as COSV59107684; called by muse, mutect2, varscan2
- DCHS2 | n.8046G>A | RNA (SNP) | VAF 133/461 reads (29%) | catalogued as COSV61769616; called by muse, mutect2, varscan2
- DCHS2 | n.7502G>A | RNA (SNP) | VAF 104/409 reads (25%) | catalogued as COSV61770568, COSV61773093; called by muse, mutect2, varscan2
- DNAI2 | c.-11-25C>T | Intron (SNP) | VAF 128/469 reads (27%) | catalogued as rs758022189; called by muse, mutect2, varscan2
- DNAI2 | c.-11-24C>T | Intron (SNP) | VAF 128/470 reads (27%) | catalogued as rs935248397; called by muse, mutect2, varscan2
- FDXR | c.178-16C>T | Intron (SNP) | VAF 149/555 reads (27%) | called by muse, mutect2, varscan2
- GRB7 | c.-20C>T | 5'UTR (SNP) | VAF 85/311 reads (27%) | catalogued as rs1200174313; called by muse, mutect2, varscan2
- GRIA1 | c.2385+817G>A | Intron (SNP) | VAF 60/242 reads (25%) | catalogued as rs372301831; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22386C>T | Intron (SNP) | VAF 98/356 reads (28%) | catalogued as rs950029968, COSV67483503; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-19360C>T | Intron (SNP) | VAF 81/272 reads (30%) | called by muse, mutect2, varscan2
- LOXHD1 | chr18:46477187 C>T | 3'Flank (SNP) | VAF 176/433 reads (41%) | catalogued as rs975442350; called by muse, mutect2, varscan2
- LY6G6E | chr6:31712113 C>T | 3'Flank (SNP) | VAF 48/459 reads (10%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22607576 G>A | 3'Flank (SNP) | VAF 96/406 reads (24%) | called by muse, mutect2, varscan2
- SNAP25 | c.164-197G>A | Intron (SNP) | VAF 80/282 reads (28%) | catalogued as rs866219500, COSV54770122, COSV54770618, COSV54770698; called by muse, mutect2, varscan2
- SYNE1 | c.3027+94C>T | Intron (SNP) | VAF 9/253 reads (4%) | called by muse, mutect2
